Gene-level copy-number profile of tumor specimen TCGA-05-4402-01A from TCGA case TCGA-05-4402, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 57.0 years (20,819 days).
Specimen TCGA-05-4402-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e9f4c410-1ac1-4c66-b45c-930892e34e24.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-4402-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0a651c5c-6436-41c9-b7c3-97b2d157863d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 330; copy number 2: 23,262; copy number 3: 11,187; copy number 4: 22,783; copy number 5: 800; copy number 6: 1,218; copy number 8: 94; copy number 9: 20; copy number 10: 89; copy number 12: 12; copy number 14: 1; copy number 15: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-4402-01A-01D-1204-01): tumor purity 0.44, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,695,176–22,214,672, 17 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,238 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–10,307,902, 217 genes, copy number 5–10 (broad region; genes not listed).
- chr7:70,972–67,628,349, 1,278 genes, copy number 5–15 (broad region; genes not listed).
- chr7:70,837,738–70,838,013, 1 gene, copy number 14: AC073873.1.
- chr8:86,553,977–89,243,793, 22 genes, copy number 6 (within-gene range 4–6): CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, AC090578.3, RPSAP74.
- chr8:92,882,984–94,881,746, 49 genes, copy number 6 (within-gene range 4–6): AC117834.1, TRIQK, IRF5P1, MIR8084, C8orf87, LINC00535, AC016885.1, AC016885.3, AC016885.2, RNA5SP274, ZNF317P1, CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1, PDP1, MIR378D2HG, MIR378D2, PSMA2P2, RPL34P18, AC105081.1, AP003351.1, CDH17, AP003478.1, GEM, RPS4XP10, RAD54B, FSBP, VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1, INTS8.
- chr8:111,376,639–128,564,679, 208 genes, copy number 6 (broad region; genes not listed).
- chr8:129,685,401–139,508,971, 102 genes, copy number 6–8 (broad region; genes not listed).
- chr8:140,636,281–145,066,685, 197 genes, copy number 6 (broad region; genes not listed).
- chr17:19,215,615–22,706,703, 164 genes, copy number 6–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 330. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
